Somatic mutation profile of tumor specimen HCM-CSHL-0366-C50-01A (aliquot HCM-CSHL-0366-C50-01A-11D-A78J-36) from HCMI case HCM-CSHL-0366-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.9 years (17,140 days).
Specimen HCM-CSHL-0366-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 383ef178-26cb-4b87-a132-ae7290956146.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0366-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0366-C50-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/958427e6-8924-4b09-b9e9-42a8953e499e

The open-access MAF lists 119 somatic variants for this specimen: 81 protein-altering or splice-affecting, 20 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 20, Intron 11, Nonsense Mutation 6, 5'UTR 3, RNA 2, 3'UTR 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.723dup p.E242* | Frame Shift Ins (INS) | VAF 65/284 reads (23%) | catalogued as rs1060500115; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 46/295 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BHLHE22 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs1296848862, COSV58861327, COSV58863066; called by muse, mutect2, varscan2
- BRCC3 | c.810G>C p.K270N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57461779; called by muse, mutect2
- CCSER2 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV56503909; called by muse, mutect2, varscan2
- COL6A3 | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.104); catalogued as COSV55115801; called by muse, mutect2, varscan2
- DENND4A | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs756556371; called by muse, mutect2, varscan2
- DIP2A | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs1456031785; called by muse, mutect2
- DNAAF3 | c.1354G>A p.A452T (on ENST00000524407 / NM_001256715.2; = p.A499T on NM_178837.4) | Missense Mutation (SNP) | VAF 32/419 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs546293010, COSV61277795; called by muse, mutect2
- EME1 | c.405G>C p.W135C | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV99869077; called by mutect2, varscan2
- EMILIN1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs370534632, COSV53154338; called by muse, mutect2, varscan2
- FGF3 | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV61925337; called by muse, mutect2, varscan2
- FREM2 | c.6818G>C p.R2273T | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54834672; called by muse, mutect2
- GARS1 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 39/467 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs374616031; ClinVar: likely benign; called by muse, mutect2
- GRM3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.223); catalogued as COSV64471712, COSV64478005; called by muse, mutect2, varscan2
- KDM6A | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65038034, COSV65040758; called by muse, mutect2, varscan2
- KIF13B | c.2083C>G p.L695V | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as rs1277630291; called by muse, mutect2, varscan2
- KRTAP21-2 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.171); catalogued as rs1443847783; called by muse, mutect2
- LYST | c.8003G>A p.R2668K | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1416779664; called by muse, mutect2, varscan2
- MARCHF1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.885); catalogued as rs1448736424; called by muse, mutect2
- MUC6 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 45/513 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547156930, COSV70133356; called by muse, mutect2
- MVD | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1177828138, COSV55367769; called by muse, mutect2
- NEFH | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs1217375234; called by muse, mutect2, varscan2
- NEFH | c.2857G>C p.E953Q | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV60216259; called by muse, mutect2, varscan2
- NPIPB15 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 130/1782 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.982); catalogued as rs754177956; called by muse, mutect2
- OR5AP2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100266315; called by muse, mutect2, varscan2
- PCDHGB1 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs202007643; called by muse, mutect2
- PIEZO2 | c.6383A>T p.Q2128L | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1228178324, COSV53287407; called by muse, mutect2
- PILRA | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 51/387 reads (13%) | catalogued as rs1475095141; called by muse, mutect2, varscan2
- PLVAP | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs148432183, COSV53086417; called by muse, mutect2
- POLQ | c.7321C>T p.Q2441* | Nonsense Mutation (SNP) | VAF 37/194 reads (19%) | catalogued as rs777186145, COSV99953238; called by muse, mutect2, varscan2
- RAD51C | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 17/206 reads (8%) | catalogued as COSV61677447; called by muse, mutect2
- RAPGEF6 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs1162961940, COSV99726095; called by muse, mutect2
- RBM23 | c.412G>A p.G138R (on ENST00000359890 / NM_001077351.2; = p.G122R on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100321327; called by muse, mutect2
- SERPINE3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 56/616 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV68546061; called by muse, mutect2
- SOX6 | c.1440C>G p.I480M (on ENST00000528429 / NM_001145819.2; = p.I453M on NM_017508.3) | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1464496710, COSV99074036; called by muse, mutect2
- SYNE1 | c.2360C>T p.A787V (on ENST00000367255 / NM_182961.4; = p.A794V on NM_033071.3) | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs147406318, COSV54951838; called by muse, mutect2, varscan2
- TSSC4 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763464142, COSV50174081; called by muse, mutect2, varscan2
- ZNF469 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 42/614 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1430171586; called by muse, mutect2
- ADGRG6 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- ANK2 | c.4525G>C p.E1509Q | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CACHD1 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- CARMIL2 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); called by muse, mutect2
- CAT | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- CCDC3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); called by muse, mutect2
- CKAP5 | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGA1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CNGB1 | c.3254G>C p.R1085T | Missense Mutation (SNP) | VAF 48/524 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- CT83 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2
- CUL9 | c.7486G>C p.E2496Q | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- CYP3A4 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2
- DAGLB | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- DGKG | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.157); called by muse, mutect2
- DPYS | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EPB41L4B | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); called by muse, mutect2
- FERMT1 | c.307A>T p.N103Y | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FLNA | c.7769T>A p.L2590Q (on ENST00000369850 / NM_001110556.2; = p.L2582Q on NM_001456.3) | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GHR | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- INAVA | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- JRK | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- LOXHD1 | c.4789T>A p.W1597R | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.583); called by muse, mutect2
- MAPK9 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- MCC | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); called by muse, mutect2
- MID1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- NPM3 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OLFML2A | c.1689G>C p.E563D | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PATL2 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2
- PCDHB6 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 35/223 reads (16%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.1103G>A p.R368K (on ENST00000408927 / NM_001100427.2; = p.R369K on NM_021159.5) | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- RELN | c.9716G>A p.G3239E | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- RPA4 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SLC35F5 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- SMARCA1 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- SPDYE1 | c.621C>G p.F207L | Missense Mutation (SNP) | VAF 56/698 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.194); called by muse, mutect2
- STAG1 | c.3073T>G p.Y1025D | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- TRMT10B | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2
- WDFY3 | c.8917C>T p.H2973Y | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XCL2 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- ZNF665 | c.309G>T p.E103D (on ENST00000600412; = p.E168D on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2
- ZNF780A | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ZNF800 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A3 | c.1872C>G p.L624= | Silent (SNP) | VAF 44/322 reads (14%) | catalogued as COSV55086748; called by muse, mutect2, varscan2
- DHX37 | c.231G>A p.K77= | Silent (SNP) | VAF 33/269 reads (12%) | called by muse, mutect2, varscan2
- DPH2 | c.366C>T p.F122= | Silent (SNP) | VAF 39/542 reads (7%) | catalogued as rs999912667; called by muse, mutect2
- EVX2 | c.393C>T p.L131= | Silent (SNP) | VAF 20/221 reads (9%) | catalogued as rs201090389; called by muse, mutect2
- FAM171A2 | c.2460G>A p.L820= | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- ISLR2 | c.1374C>T p.R458= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs780483337; called by muse, mutect2
- KIAA0825 | c.2085G>A p.L695= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- LIN7B | c.63C>T p.L21= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs1447580686, COSV99674359; called by muse, varscan2
- LTBP4 | c.591C>A p.L197= (on ENST00000308370 / NM_001042544.1; = p.L160= on NM_003573.2) | Silent (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- OSBP | c.2169G>T p.L723= | Silent (SNP) | VAF 62/330 reads (19%) | called by muse, mutect2, varscan2
- PATL2 | c.1608G>A p.R536= | Silent (SNP) | VAF 22/343 reads (6%) | called by muse, mutect2
- PCCA | c.525C>T p.G175= | Silent (SNP) | VAF 13/203 reads (6%) | catalogued as rs151168308; ClinVar: likely benign; called by muse, mutect2
- PGM1 | c.117C>T p.F39= | Silent (SNP) | VAF 96/715 reads (13%) | called by muse, mutect2, varscan2
- PTBP1 | c.1218C>T p.I406= (on ENST00000349038 / NM_031991.4; = p.I432= on NM_002819.5) | Silent (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- RFC4 | c.591C>T p.F197= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs1476853269; called by muse, mutect2
- SLC24A1 | c.2013C>T p.I671= | Silent (SNP) | VAF 46/312 reads (15%) | called by muse, varscan2
- SPOUT1 | c.579C>T p.I193= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as rs1205045558; called by muse, mutect2, varscan2
- SSTR4 | c.411C>T p.L137= | Silent (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- THEMIS | c.1083A>G p.E361= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs1021485276; called by muse, mutect2, varscan2
- WFDC13 | c.60G>T p.V20= | Silent (SNP) | VAF 10/308 reads (3%) | called by muse, mutect2
- BOD1P2 | n.59C>T | RNA (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- C1orf131 | c.693+9G>C | Intron (SNP) | VAF 22/434 reads (5%) | called by muse, mutect2
- CD19 | c.1085-25C>T | Intron (SNP) | VAF 15/106 reads (14%) | catalogued as rs770883566; called by muse, mutect2
- CLK1 | c.-1+359G>A | Intron (SNP) | VAF 9/131 reads (7%) | catalogued as rs751024838; called by muse, mutect2
- CTSF | c.-10C>T | 5'UTR (SNP) | VAF 15/220 reads (7%) | called by muse, mutect2
- ENDOV | c.-25C>G | 5'UTR (SNP) | VAF 50/502 reads (10%) | called by muse, mutect2, varscan2
- MCRIP1 | c.-48-1189C>A | Intron (SNP) | VAF 29/284 reads (10%) | called by muse, mutect2, varscan2
- MYO10 | c.-37G>C | 5'UTR (SNP) | VAF 31/170 reads (18%) | called by muse, mutect2, varscan2
- NEFH | c.*34G>T | 3'UTR (SNP) | VAF 46/498 reads (9%) | called by muse, mutect2
- PRKAG3 | c.775-43G>A | Intron (SNP) | VAF 15/301 reads (5%) | called by muse, mutect2
- RPAIN | c.314-699C>G | Intron (SNP) | VAF 5/132 reads (4%) | called by muse, mutect2
- SDHAP2 | n.1083G>C | RNA (SNP) | VAF 27/176 reads (15%) | called by muse, mutect2, varscan2
- SMARCA4 | c.2505+17G>A | Intron (SNP) | VAF 40/418 reads (10%) | called by muse, mutect2
- TSC2 | c.3884-54G>A | Intron (SNP) | VAF 14/171 reads (8%) | called by muse, mutect2
- TTBK2 | c.823-7191G>A | Intron (SNP) | VAF 49/422 reads (12%) | catalogued as rs771535501; called by muse, mutect2, varscan2
- XIAP | c.*5594C>T | 3'UTR (SNP) | VAF 14/178 reads (8%) | catalogued as rs977189715; called by muse, mutect2
- YARS1 | c.1334+48G>C | Intron (SNP) | VAF 48/229 reads (21%) | called by muse, mutect2, varscan2
- ZNF692 | c.-12-196C>T | Intron (SNP) | VAF 38/420 reads (9%) | called by muse, mutect2
